Somatic mutation profile of tumor specimen TCGA-BJ-A45I-01A (aliquot TCGA-BJ-A45I-01A-11D-A23U-08) from TCGA case TCGA-BJ-A45I, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.4 years (18,767 days).
Specimen TCGA-BJ-A45I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa892b89-72d1-4dad-9ba5-c8c2ebae8d2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A45I-10A (Blood Derived Normal), aliquot TCGA-BJ-A45I-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5959257-b509-4288-b2cc-0c5036f3803e

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C11orf58 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as COSV57179549; called by muse, mutect2
- CDH4 | c.2677T>C p.Y893H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64679485; called by muse, mutect2, varscan2
- LRGUK | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV53645140; called by muse, mutect2
- ANK2 | c.826A>C p.R276= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV52194531; called by muse, mutect2, varscan2
- MAML1 | c.831G>A p.E277= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV52989852; called by muse, mutect2
- AP000769.5 | chr11:65500800 del TGGAACTTACTTATGGTAACCTTTTATTTATTTTCTAATA | 5'Flank (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
